Gene-level copy-number profile of tumor specimen TCGA-02-0064-01A from TCGA case TCGA-02-0064, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.0 years (18,280 days).
Specimen TCGA-02-0064-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.21e47bd5-57e7-4c0e-91e7-19fec33c4fb4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0064-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6545d8b8-a06c-4d4e-aef0-e03ca7400342

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 107; copy number 1: 7,042; copy number 2: 47,033; copy number 3: 5,513; copy number 4: 88; copy number 5: 1; copy number 7: 8; copy number 42: 1; copy number 44: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0064-01): tumor purity 0.61, ploidy 1.97, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 107 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,507,452–19,786,928, 2 genes (within-gene range 0–1): SLC24A2, C11orf98P1.
- chr9:19,926,094–24,592,104, 86 genes (broad region; genes not listed).
- chr9:25,088,811–27,104,728, 18 genes: RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1.
- chr9:27,829,276–27,844,481, 1 gene: AL360014.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 25 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,300,322, 8 genes, copy number 7: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr7:54,933,699–55,713,252, 17 genes, copy number 5–44: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P.

Autosomal genes at a single copy (total copy number 1): 4,655. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
